Somatic mutation profile of tumor specimen TCGA-77-7463-01A (aliquot TCGA-77-7463-01A-11D-2042-08) from TCGA case TCGA-77-7463, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 75.3 years (27,520 days).
Specimen TCGA-77-7463-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c72266df-d587-43cd-ad92-4d7dab2408ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-7463-10A (Blood Derived Normal), aliquot TCGA-77-7463-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3960c5cb-3c6a-4cbc-84c9-bf5690a4576e

The open-access MAF lists 425 somatic variants for this specimen: 321 protein-altering or splice-affecting, 94 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 280, Silent 94, Nonsense Mutation 13, Frame Shift Del 12, Splice Site 10, RNA 4, 3'UTR 2, Frame Shift Ins 2, Intron 2, 5'UTR 2, Splice Region 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.875del p.N292Mfs*15 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs786204905; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 27/45 reads (60%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, mutect2, varscan2
- A1CF | c.509C>G p.P170R | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV50991082, COSV99255611; called by muse, mutect2, varscan2
- AC092442.1 | c.118G>T p.G40* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV51525720; called by muse, mutect2, varscan2
- ADAM32 | c.1367C>G p.P456R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.093); catalogued as rs1356397177, COSV101165335, COSV65953493; called by muse, mutect2
- ADAMTS12 | c.2694C>A p.C898* | Nonsense Mutation (SNP) | VAF 83/127 reads (65%) | catalogued as COSV100710542; called by muse, mutect2, varscan2
- ADAMTS16 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 24/180 reads (13%) | catalogued as COSV99940648; called by muse, mutect2, varscan2
- ADAMTS4 | c.702C>A p.H234Q | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100917392, COSV63487517; called by muse, mutect2, varscan2
- ADAMTS7 | c.3854C>A p.P1285H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101183065; called by muse, mutect2, varscan2
- ADAMTS9 | c.5431G>A p.D1811N | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); catalogued as rs770275540, COSV55788486; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1570A>G p.I524V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs745414432, COSV99717817; called by muse, mutect2, varscan2
- ADCY6 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs777424589, COSV57166948; called by muse, mutect2
- ADGRD1 | c.1249A>G p.R417G | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1380755747, COSV99894683; called by muse, mutect2, varscan2
- ADH1B | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100520682; called by muse, mutect2
- AHNAK2 | c.5362A>T p.S1788C | Missense Mutation (SNP) | VAF 142/530 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.871); catalogued as COSV100316623; called by muse, mutect2, varscan2
- AKAP6 | c.2879+1G>T p.X960_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | catalogued as COSV55239335; called by muse, mutect2, varscan2
- AKAP9 | c.6664A>G p.I2222V (on ENST00000359028; = p.I2198V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100662169; called by muse, mutect2, varscan2
- ALAS2 | c.1157C>A p.S386Y | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58190529, COSV58191727; called by muse, mutect2, varscan2
- ALOX12B | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100046800; called by muse, mutect2, varscan2
- ALPK2 | c.1309C>A p.Q437K | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV100864241; called by muse, mutect2, varscan2
- ALPK2 | c.1308C>A p.H436Q | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as rs141706043; called by muse, mutect2, varscan2
- AMER1 | c.2075A>T p.E692V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100365713; called by muse, mutect2, varscan2
- ANKRD6 | c.46G>C p.V16L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV100329629, COSV60229553, COSV60237701; called by muse, mutect2, varscan2
- APOA4 | c.427C>A p.R143S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as rs756971543, COSV100759293, COSV100759300; called by muse, mutect2, varscan2
- ARHGEF17 | c.2076G>T p.W692C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.237); catalogued as COSV99735159; called by muse, mutect2, varscan2
- ARHGEF6 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.406); catalogued as COSV99166408; called by muse, mutect2
- ASCC3 | c.1813G>T p.V605L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as rs776383149, COSV100225465; called by muse, mutect2, varscan2
- ASIC4 | c.303G>T p.M101I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV100761634; called by muse, mutect2, varscan2
- ASTN1 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs966220857, COSV99920958; called by muse, mutect2, varscan2
- ATP2B4 | c.1644G>C p.Q548H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100397299; called by muse, mutect2
- AVP | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100977767; called by muse, mutect2, varscan2
- BORCS7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV54916418; called by muse, mutect2, varscan2
- BRD4 | c.3695G>T p.R1232L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as COSV54583371, COSV99650198; called by muse, mutect2, varscan2
- BRWD3 | c.3387G>T p.L1129F | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100955845; called by muse, mutect2, varscan2
- BTN1A1 | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99764277; called by muse, mutect2
- C1orf158 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 70/117 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99847254; called by muse, mutect2, varscan2
- C2orf78 | c.2027A>T p.D676V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101280940; called by muse, mutect2, varscan2
- CALCR | c.1435A>G p.I479V (on ENST00000649521 / NM_001164737.2; = p.I463V on NM_001742.4) | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as COSV100810454; called by muse, mutect2, varscan2
- CCDC150 | c.2599G>A p.V867M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs1401150327, COSV99776699; called by muse, mutect2, varscan2
- CCDC33 | c.1749G>T p.R583S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV99173225; called by muse, mutect2, varscan2
- CCNY | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs1385799050, COSV99590417; called by muse, mutect2, varscan2
- CCR2 | c.615G>C p.M205I | Missense Mutation (SNP) | VAF 164/293 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV99432219; called by muse, mutect2, varscan2
- CD163 | c.455C>A p.S152* | Nonsense Mutation (SNP) | VAF 102/285 reads (36%) | catalogued as COSV100775755; called by muse, mutect2, varscan2
- CD1E | c.913T>C p.S305P | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.142); catalogued as COSV100936950; called by muse, mutect2, varscan2
- CD46 | c.1178G>C p.*393Sext*38 | Nonstop Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as rs780969870, COSV100522826; called by mutect2, varscan2
- CDH18 | c.1635C>G p.N545K | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV99933294; called by muse, mutect2, varscan2
- CDH18 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.071); catalogued as COSV99933297; called by muse, mutect2, varscan2
- CDK13 | c.1334T>A p.L445Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99475298; called by muse, mutect2, varscan2
- CEP192 | c.7474A>C p.R2492= | Splice Region (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100380902; called by muse, mutect2, varscan2
- CEP250 | c.530T>A p.L177H | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100698838; called by muse, mutect2, varscan2
- CFAP206 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV99739306; called by muse, mutect2, varscan2
- CFHR1 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100258723; called by muse, mutect2, varscan2
- CHIA | c.822C>A p.S274R (on ENST00000343320; = p.S166R on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV100588622; called by muse, mutect2, varscan2
- CIITA | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV100161640; called by muse, mutect2, varscan2
- CLEC4G | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.33); PolyPhen benign (0.106); catalogued as COSV100183620; called by muse, mutect2, varscan2
- CNR1 | c.810C>G p.H270Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV100759192; called by muse, mutect2, varscan2
- COL22A1 | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs760204618, COSV57339190; called by muse, mutect2, varscan2
- COL4A3 | c.4877C>G p.S1626* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | catalogued as COSV101170143; called by muse, mutect2
- CPZ | c.223G>T p.A75S (on ENST00000360986 / NM_001014447.3; = p.A64S on NM_003652.3) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV100248868; called by muse, mutect2, varscan2
- CR2 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV65508969; called by muse, mutect2, varscan2
- CRB1 | c.1961C>A p.T654N | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as CM057652, COSV100957646, COSV100957758; called by muse, mutect2, varscan2
- CRISP2 | c.605C>A p.T202N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV100188948, COSV59254094; called by muse, mutect2, varscan2
- CSMD2 | c.10315A>G p.K3439E | Missense Mutation (SNP) | VAF 158/270 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99587901; called by muse, mutect2, varscan2
- CUL3 | c.1485+1G>T p.X495_splice | Splice Site (SNP) | VAF 61/137 reads (45%) | catalogued as COSV100024000; called by muse, mutect2, varscan2
- CYP21A2 | c.940-1G>T p.X314_splice | Splice Site (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100926104; called by muse, mutect2, varscan2
- DBF4B | c.1427A>C p.H476P | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.012); catalogued as COSV100154388; called by muse, mutect2, varscan2
- DCAF13 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 32/71 reads (45%) | catalogued as COSV99885146; called by muse, mutect2, varscan2
- DCSTAMP | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV99886336, COSV99887072; called by muse, mutect2, varscan2
- DIAPH2 | c.2783del p.R928Lfs*20 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as COSV61293684; called by mutect2, pindel, varscan2
- DLGAP2 | c.1093T>A p.Y365N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV101421468; called by muse, mutect2
- DNAH7 | c.4623A>T p.L1541F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100414514; called by muse, mutect2, varscan2
- DROSHA | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 17/148 reads (11%) | catalogued as COSV100757547; called by muse, mutect2, varscan2
- DSG4 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV100355612; called by muse, mutect2, varscan2
- DST | c.9386A>T p.K3129M | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.077); catalogued as COSV99753397; called by muse, mutect2, varscan2
- DTNA | c.1544T>A p.L515Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99311826; called by muse, mutect2, varscan2
- EEF1A2 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99419202; called by muse, mutect2, varscan2
- EHD2 | c.1190T>C p.L397P | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99621788; called by muse, mutect2, varscan2
- ESYT2 | c.617G>T p.W206L (on ENST00000613624; = p.W130L on NM_020728.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99276426; called by muse, mutect2, varscan2
- EVC2 | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM098970, COSV100185482; called by muse, mutect2, varscan2
- F13B | c.1009del p.E337Rfs*24 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | catalogued as COSV66375206; called by mutect2, pindel, varscan2
- FAF2 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs760301855, COSV99990351; called by muse, varscan2
- FAHD2A | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV99271931; called by muse, mutect2, varscan2
- FAM111A | c.1485G>C p.K495N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV100659348; called by muse, mutect2
- FAM135B | c.2344G>C p.A782P | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52703678, COSV99421357; called by muse, mutect2, varscan2
- FAM153B | c.371A>T p.D124V (on ENST00000253490; = p.D47V on NM_001265615.1) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV99498840, COSV99498892; called by muse, mutect2, varscan2
- FAM83B | c.2906G>T p.G969V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV60921326, COSV60922690; called by muse, mutect2, varscan2
- FAT3 | c.3736G>T p.D1246Y | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53130925; called by muse, mutect2, varscan2
- FBXO47 | c.1088G>T p.C363F | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100960621; called by muse, mutect2, varscan2
- FMN2 | c.3397C>T p.P1133S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.029); catalogued as COSV100144171, COSV60450071; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.428A>T p.E143V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); catalogued as COSV100436124; called by muse, mutect2, varscan2
- FRK | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101661761; called by muse, mutect2, varscan2
- FUT1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as rs1358165719, COSV55809857; called by muse, mutect2, varscan2
- GABBR1 | c.1029C>G p.F343L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV100589550, COSV63541598; called by muse, mutect2, varscan2
- GALNTL6 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101560192; called by muse, mutect2, varscan2
- GCKR | c.1445C>T p.T482I | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1024943882, COSV99268910; called by muse, mutect2, varscan2
- GIMAP1 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV100212042; called by muse, mutect2
- GLI1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV99953873; called by muse, mutect2, varscan2
- GNPNAT1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as rs200614465, COSV99369489; called by muse, mutect2, varscan2
- GPBP1L1 | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 86/126 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99322094; called by muse, mutect2, varscan2
- GPC3 | c.1293-2A>T p.X431_splice | Splice Site (SNP) | VAF 17/28 reads (61%) | catalogued as COSV100892890; called by muse, mutect2, varscan2
- GPN3 | c.620G>C p.R207T | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV99959778; called by muse, mutect2, varscan2
- GPR148 | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV99998552; called by muse, mutect2
- GPR155 | c.1999A>T p.I667F | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV99789779; called by muse, mutect2, varscan2
- GRIK2 | c.1085T>C p.L362P | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100024536; called by muse, mutect2
- GRM6 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs759761288, CM1514171, COSV51433504; called by muse, mutect2, varscan2
- H1-3 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99768567, COSV99768682; called by muse, mutect2, varscan2
- HBG2 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100400600, COSV57964310; called by mutect2, varscan2
- HEATR5B | c.5845C>G p.L1949V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as rs765893925, COSV99248781; called by muse, varscan2
- HEPHL1 | c.2334T>G p.I778M | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100243747; called by muse, mutect2
- HERC2 | c.7524A>G p.I2508M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs766315236, COSV99872115; called by muse, mutect2
- HSP90AA1 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99355152; called by muse, mutect2, varscan2
- HTR3A | c.1391A>T p.Y464F | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100248357; called by muse, mutect2, varscan2
- HTR3B | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV52747099, COSV99491858; called by muse, mutect2, varscan2
- HTR5A | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55287643, COSV99839555; called by muse, mutect2, varscan2
- IL7R | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV57407218, COSV57407741, COSV57410867; called by muse, mutect2, varscan2
- IQSEC1 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as COSV56225383; called by muse, mutect2, varscan2
- ISX | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100434040; called by muse, mutect2, varscan2
- ITIH2 | c.613C>A p.L205M | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100623236; called by muse, mutect2, varscan2
- JPH3 | c.2060A>T p.E687V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99413092; called by muse, mutect2, varscan2
- KCNH1 | c.1409C>A p.A470D (on ENST00000271751 / NM_172362.3; = p.A443D on NM_002238.4) | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99658230; called by muse, mutect2, varscan2
- KCNK13 | c.580G>C p.V194L | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV56412467, COSV99965591; called by muse, mutect2, varscan2
- KCNS2 | c.383T>A p.V128E | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99750950; called by muse, mutect2, varscan2
- KIAA0895 | c.263G>T p.S88I (on ENST00000297063 / NM_001100425.2; = p.S37I on NM_015314.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.202); catalogued as COSV99766623; called by muse, mutect2, varscan2
- KIAA1109 | c.5303G>A p.R1768H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.732); catalogued as rs772761018, COSV52687226; called by muse, mutect2, varscan2
- KLK15 | c.665T>G p.I222S | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100032616; called by muse, mutect2, varscan2
- KNG1 | c.68C>G p.S23C | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as COSV99405356; called by muse, mutect2, varscan2
- KRT1 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs1358206182, COSV99358614; called by muse, mutect2, varscan2
- LAMC2 | c.2510C>G p.A837G | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99917264; called by muse, mutect2, varscan2
- LDB2 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as COSV100453179; called by muse, mutect2, varscan2
- LEPR | c.989C>A p.T330K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as COSV100756458; called by muse, mutect2, varscan2
- LETM2 | c.387A>T p.E129D (on ENST00000379957 / NM_001286819.2; = p.E82D on NM_144652.3) | Missense Mutation (SNP) | VAF 62/83 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99907329; called by muse, mutect2, varscan2
- LIN28B | c.150C>A p.N50K | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV100558656; called by muse, mutect2, varscan2
- LPIN2 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.265); catalogued as rs771573884, COSV99858139; called by muse, mutect2, varscan2
- LRIT3 | c.1841A>G p.E614G | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as COSV100015979; called by muse, mutect2, varscan2
- LRR1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100023057; called by muse, mutect2, varscan2
- LRRC3B | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV101185747, COSV67520069; called by muse, mutect2, varscan2
- LRRC66 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as COSV100602897; called by muse, mutect2, varscan2
- LY6H | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as COSV100713871; called by muse, mutect2, varscan2
- MAD2L1 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99633770; called by muse, mutect2, varscan2
- MAGEB6 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.068); catalogued as rs747759841, COSV100983696, COSV100983698; called by muse, mutect2, varscan2
- MAP3K15 | c.2773G>T p.E925* | Nonsense Mutation (SNP) | VAF 25/42 reads (60%) | catalogued as COSV100134412; called by muse, mutect2, varscan2
- MAP3K9 | c.1914-2A>T p.X638_splice | Splice Site (SNP) | VAF 48/155 reads (31%) | catalogued as COSV101173546; called by muse, mutect2
- MARCHF5 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV100739575; called by muse, mutect2, varscan2
- MCHR2 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1010832977, COSV99911733; called by muse, mutect2, varscan2
- MDM1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as COSV100291731; called by muse, mutect2, varscan2
- MDN1 | c.11527C>G p.Q3843E | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV101021012; called by muse, mutect2, varscan2
- MECOM | c.1647C>G p.S549R (on ENST00000468789 / NM_001105078.4; = p.S737R on NM_004991.4) | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV99244382; called by muse, mutect2, varscan2
- MICALL2 | c.487A>G p.R163G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs531616914, COSV99875793; called by muse, varscan2
- MKLN1 | c.1524G>T p.M508I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.054); catalogued as COSV100759761; called by muse, mutect2, varscan2
- MRGPRX3 | c.429T>G p.C143W | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101283507; called by muse, mutect2, varscan2
- MTMR6 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV101110744; called by muse, mutect2, varscan2
- MUC16 | c.40682G>T p.G13561V | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.998); catalogued as COSV101109744; called by muse, mutect2, varscan2
- MUC21 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.167); catalogued as COSV100888846; called by muse, mutect2, varscan2
- MYO18B | c.2040G>T p.M680I | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as COSV100123070; called by muse, mutect2, varscan2
- MYO1G | c.2304C>A p.Y768* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV99348590; called by muse, mutect2, varscan2
- NAV3 | c.3469T>C p.S1157P | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.997); catalogued as COSV99888716; called by muse, mutect2, varscan2
- NCKAP5L | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs773927583, COSV100258530; called by muse, mutect2, varscan2
- NCOA2 | c.2729C>T p.P910L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99144746; called by muse, mutect2, varscan2
- NEXMIF | c.3322A>T p.S1108C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99280252; called by muse, mutect2, varscan2
- NKX2-3 | c.544G>C p.A182P | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100755044; called by muse, mutect2, varscan2
- NLRP10 | c.1697C>A p.S566Y | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV100149576, COSV60782959; called by muse, mutect2, varscan2
- NLRP3 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100275639; called by muse, mutect2, varscan2
- NOL6 | c.3028G>A p.V1010M | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs370221885, COSV53043265; called by muse, mutect2, varscan2
- NOP9 | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV99852233; called by muse, mutect2, varscan2
- NPIPB3 | c.407C>T p.P136L (on ENST00000542817; = p.P352L on NM_130464.3) | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs1368051429, COSV101341619; called by muse, varscan2
- NXPH2 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 91/156 reads (58%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.024); catalogued as COSV99740353; called by muse, mutect2, varscan2
- OR10G7 | c.170T>C p.M57T | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs771467544, COSV100389831; called by muse, mutect2, varscan2
- OR10V1 | c.423G>T p.L141F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100275705; called by muse, mutect2, varscan2
- OR12D3 | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101011183; called by muse, mutect2, varscan2
- OR2L13 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV100813705, COSV63560800; called by muse, mutect2, varscan2
- OR2M5 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV100822782; called by muse, mutect2
- OR2M7 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs781730003, COSV100522477; called by muse, mutect2
- OR2T1 | c.158G>C p.R53P | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV100822279; called by muse, mutect2, varscan2
- OR4C11 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100155277; called by muse, mutect2, varscan2
- OR4P4 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs781088182, COSV100111549, COSV58923442; called by muse, mutect2, varscan2
- OR51F2 | c.225G>C p.L75F | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100437969; called by muse, mutect2, varscan2
- OR5B12 | c.475G>C p.G159R | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as rs1261467809, COSV56904570, COSV56906992; called by muse, mutect2
- OR5H1 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100641653, COSV63402571; called by muse, varscan2
- OR8H2 | c.28G>C p.V10L | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100542229; called by muse, mutect2, varscan2
- OR8K5 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57887797, COSV57888206; called by muse, mutect2, varscan2
- OTOP2 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs138035314, COSV100172720; called by muse, mutect2, varscan2
- PCDH15 | c.3778G>T p.V1260L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.78); catalogued as COSV100217984; called by muse, mutect2, varscan2
- PDCL3 | c.455C>A p.T152K | Missense Mutation (SNP) | VAF 64/115 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.134); catalogued as COSV99959520; called by muse, mutect2, varscan2
- PDE4DIP | c.4303A>G p.K1435E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV100518051; called by mutect2, varscan2
- PEG3 | c.4280G>A p.G1427E | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as COSV99688097; called by muse, mutect2, varscan2
- PFKFB1 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | PolyPhen benign (0.013); catalogued as rs1362208113, COSV100895648; called by muse, mutect2
- PGBD2 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100251933; called by muse, mutect2, varscan2
- PGR | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV99677838; called by muse, mutect2, varscan2
- PIK3CB | c.10A>G p.S4G | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV100005385, COSV56683279; called by muse, mutect2, varscan2
- PKDREJ | c.3217C>A p.P1073T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99478629; called by muse, mutect2, varscan2
- PLEC | c.10294G>T p.V3432L (on ENST00000322810 / NM_201380.4; = p.V3322L on NM_000445.5) | Missense Mutation (SNP) | VAF 100/153 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100512393; called by muse, mutect2, varscan2
- PLEC | c.9385A>G p.I3129V (on ENST00000322810 / NM_201380.4; = p.I3019V on NM_000445.5) | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV100512398; called by muse, mutect2, varscan2
- PLEKHG2 | c.1862C>G p.S621C | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs889500996, COSV99217107; called by muse, mutect2, varscan2
- PLEKHH2 | c.1017G>T p.E339D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV56750287; called by muse, mutect2, varscan2
- PLXNA4 | c.5681G>C p.S1894T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100323391; called by muse, mutect2, varscan2
- PNLIPRP3 | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV100982434, COSV65047087; called by muse, mutect2, varscan2
- PNPLA1 | c.979C>A p.P327T (on ENST00000394571 / NM_001374623.1; = p.P232T on NM_173676.2) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.04); catalogued as COSV100462858; called by muse, mutect2, varscan2
- POPDC3 | c.820C>A p.R274S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99633551; called by muse, mutect2, varscan2
- PPP1R12A | c.2440A>T p.I814L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99700147; called by muse, mutect2
- PPP1R3A | c.963G>C p.L321F | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV99492388; called by muse, mutect2, varscan2
- PPP2R3A | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.031); catalogued as rs1333096177, COSV53860206; called by muse, mutect2, varscan2
- PRAMEF4 | c.1181T>A p.M394K | Missense Mutation (SNP) | VAF 227/350 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV99339650; called by muse, mutect2, varscan2
- PRDM14 | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.601); catalogued as COSV99400001; called by muse, mutect2, varscan2
- PRDM2 | c.1220G>T p.R407L | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52442323, COSV99341236; called by muse, mutect2, varscan2
- PROM1 | c.602T>C p.L201S | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101477065; called by muse, mutect2, varscan2
- PRSS35 | c.344del p.G115Efs*25 | Frame Shift Del (DEL) | VAF 37/87 reads (43%) | catalogued as COSV100864009; called by mutect2, pindel, varscan2
- PSMA8 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100378735; called by muse, mutect2, varscan2
- PSPC1 | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100142225, COSV100142429; called by muse, mutect2, varscan2
- PTCHD4 | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.751); catalogued as COSV100260479; called by muse, mutect2, varscan2
- PTPRD | c.4178A>C p.D1393A | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644038; called by muse, mutect2
- PTPRZ1 | c.6253G>T p.G2085C | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564923087, COSV101099851; called by muse, mutect2, varscan2
- RAI14 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs867459274, COSV54290391; called by muse, mutect2
- RBM43 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100508537; called by muse, mutect2, varscan2
- REG1A | c.125C>A p.A42D | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52068258; called by muse, mutect2
- REG3A | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV100532610; called by muse, mutect2, varscan2
- REPIN1 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as rs950574585, COSV101262601; called by muse, mutect2, varscan2
- RFX7 | c.1352A>G p.H451R (on ENST00000559447 / NM_001368074.1; = p.H548R on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs772081148, COSV100428443; called by muse, varscan2
- RICTOR | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV99704648; called by muse, mutect2
- RING1 | c.874G>T p.V292L | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100761739; called by muse, mutect2, varscan2
- RNF152 | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV100455077; called by muse, mutect2, varscan2
- ROR2 | c.2317C>A p.L773M | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100995642; called by muse, mutect2, varscan2
- RTTN | c.5317G>T p.A1773S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs866069161, COSV55348273, COSV99731669; called by muse, mutect2, varscan2
- RUNX1T1 | c.1006C>A p.R336S (on ENST00000265814 / NM_001198628.1; = p.R309S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV56150330, COSV56152929; called by muse, mutect2, varscan2
- RXRG | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100717381; called by muse, mutect2, varscan2
- RYR3 | c.2004G>T p.Q668H | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101212306, COSV66797701; called by muse, mutect2, varscan2
- SEPTIN6 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 102/184 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100595506; called by muse, mutect2, varscan2
- SERPINA9 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs202245237, COSV100098120; called by muse, mutect2, varscan2
- SERPINH1 | c.512A>T p.Q171L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV100825039; called by muse, mutect2, varscan2
- SH3BP4 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV100749074; called by muse, mutect2, varscan2
- SHANK1 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99520665; called by muse, mutect2, varscan2
- SHCBP1L | c.405G>C p.K135N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV100840962; called by muse, mutect2
- SIAH3 | c.264C>A p.H88Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.211); catalogued as rs758491261, COSV101247790; called by muse, mutect2, varscan2
- SIGLEC5 | c.655G>T p.G219* | Nonsense Mutation (SNP) | VAF 38/83 reads (46%) | catalogued as COSV99707304; called by muse, mutect2, varscan2
- SLC22A2 | c.1329C>G p.I443M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100870963; called by muse, mutect2, varscan2
- SLC25A16 | c.785A>T p.D262V | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770045; called by muse, mutect2, varscan2
- SLC30A10 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as COSV100751463; called by muse, mutect2, varscan2
- SLC30A8 | c.240A>G p.I80M | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs777205285, COSV101438301; called by muse, mutect2, varscan2
- SLC35B3 | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1291189899, COSV101109784; called by muse, mutect2, varscan2
- SLC44A5 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100901578, COSV63771932; called by muse, mutect2, varscan2
- SLC5A1 | c.1281-1G>T p.X427_splice | Splice Site (SNP) | VAF 9/124 reads (7%) | catalogued as rs1299672737, COSV99833290; called by muse, mutect2
- SLC5A12 | c.1427G>T p.C476F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101237657; called by muse, mutect2, varscan2
- SLC6A1 | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99822578; called by muse, mutect2
- SLC6A6 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV100692026; called by muse, mutect2, varscan2
- SLC9A6 | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV100857880; called by muse, mutect2, varscan2
- SLIT3 | c.2788A>G p.T930A | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.387); catalogued as COSV100266274; called by muse, mutect2, varscan2
- SNX18 | c.908C>G p.T303R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100410318; called by muse, mutect2, varscan2
- SNX19 | c.2002A>G p.K668E | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99772935; called by muse, mutect2, varscan2
- SPHKAP | c.4619G>T p.S1540I | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100763899; called by muse, mutect2, varscan2
- SPRED1 | c.1089A>G p.I363M | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140225135; called by muse, mutect2, varscan2
- SPTBN2 | c.2816+1G>T p.X939_splice | Splice Site (SNP) | VAF 45/115 reads (39%) | catalogued as COSV100018736; called by muse, mutect2, varscan2
- STAT4 | c.1627T>A p.L543I | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.81); PolyPhen benign (0.152); catalogued as COSV100635999; called by muse, mutect2, varscan2
- SYBU | c.1726G>C p.E576Q (on ENST00000276646 / NM_001099754.2; = p.E575Q on NM_017786.6) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759622561, COSV52614138, COSV52621940, COSV99405889; called by muse, mutect2, varscan2
- TAS2R30 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 99/350 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs777088000, COSV67862951; called by muse, varscan2
- TCF23 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV99940306; called by muse, mutect2, varscan2
- TCFL5 | c.1312A>T p.T438S | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99415672; called by muse, mutect2, varscan2
- TDRD5 | c.2475C>A p.N825K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99675859; called by muse, mutect2, varscan2
- TENM1 | c.3401G>T p.G1134V | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100949519; called by muse, mutect2, varscan2
- TGIF2LX | c.714G>C p.E238D | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV52214933, COSV99383247; called by muse, mutect2, varscan2
- THAP2 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100350389, COSV57349554; called by muse, mutect2
- THBS2 | c.1868C>A p.P623Q | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100827761, COSV64682489; called by muse, mutect2, varscan2
- TMEM132D | c.2848G>T p.V950F | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.053); catalogued as rs753245505, COSV101242660; called by muse, mutect2
- TMEM252 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101051097, COSV101051106; called by muse, mutect2, varscan2
- TMTC1 | c.430G>T p.A144S (on ENST00000539277 / NM_001193451.2; = p.A36S on NM_175861.3) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV99759201; called by muse, mutect2, varscan2
- TNFRSF11A | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs755652460, COSV99500102; called by muse, mutect2, varscan2
- TPP1 | c.1146C>T p.S382= | Splice Region (SNP) | VAF 20/49 reads (41%) | catalogued as CM120842, COSV100196237; called by muse, mutect2, varscan2
- TPR | c.6479G>A p.G2160D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100823768; called by muse, mutect2, varscan2
- TREML2 | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs774938098, COSV101530157; called by muse, mutect2, varscan2
- TRIM45 | c.1525C>G p.H509D | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56712439, COSV99868360; called by muse, mutect2, varscan2
- TRIP11 | c.1522A>T p.T508S | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99970479; called by muse, mutect2, varscan2
- TRMT10A | c.213G>T p.R71S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV99910882; called by muse, mutect2, varscan2
- TRMT112 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV99134527; called by muse, varscan2
- TRMT112 | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.101); catalogued as COSV99134529; called by muse, mutect2, varscan2
- TRPA1 | c.2525A>G p.Y842C | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); catalogued as rs760279453, COSV100083643; called by muse, mutect2, varscan2
- TRRAP | c.6215T>G p.F2072C (on ENST00000359863 / NM_001244580.1; = p.F2054C on NM_003496.3) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.626); catalogued as COSV100722254; called by muse, varscan2
- TTBK2 | c.2142G>C p.L714F | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.116); catalogued as COSV99141237; called by muse, mutect2, varscan2
- TTC3 | c.2113G>T p.D705Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100695247; called by muse, mutect2, varscan2
- TTN | c.78947G>A p.R26316K (on ENST00000591111; = p.R18892K on NM_003319.4) | Missense Mutation (SNP) | VAF 31/60 reads (52%) | PolyPhen benign (0); catalogued as rs148067743, COSV100602467; called by muse, mutect2, varscan2
- TTN | c.62188G>C p.A20730P (on ENST00000591111; = p.A13306P on NM_003319.4) | Missense Mutation (SNP) | VAF 27/54 reads (50%) | PolyPhen probably damaging (0.97); catalogued as COSV100602471; called by muse, mutect2, varscan2
- TUBA1A | c.106A>G p.M36V | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV99853671; called by muse, mutect2, varscan2
- UBR2 | c.1825A>T p.S609C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100867396; called by muse, mutect2, varscan2
- USH2A | c.6130T>A p.S2044T | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.053); catalogued as COSV100232034; called by muse, mutect2, varscan2
- UTRN | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100839750; called by muse, mutect2
- UTRN | c.8186A>G p.Q2729R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV100838300; called by muse, mutect2, varscan2
- VPS13B | c.2445G>C p.W815C | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100661412; called by muse, mutect2, varscan2
- VWA3A | c.2333T>A p.L778Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.291); catalogued as COSV100240750; called by muse, mutect2, varscan2
- WASHC2C | c.711C>A p.H237Q | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV100313868; called by muse, varscan2
- WDR7 | c.1876G>T p.V626F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV99589053; called by muse, mutect2, varscan2
- WSCD2 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.526); catalogued as COSV99774337; called by muse, mutect2, varscan2
- XIRP2 | c.5200A>T p.K1734* (on ENST00000628543; = p.K1909* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 23/37 reads (62%) | catalogued as COSV99740685; called by muse, mutect2, varscan2
- XRN1 | c.4730A>T p.K1577M | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV99377581; called by muse, mutect2, varscan2
- ZAN | c.4813A>T p.T1605S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100769462; called by muse, mutect2, varscan2
- ZFPM2 | c.1468C>A p.P490T | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1318277987, COSV101023101; called by muse, mutect2, varscan2
- ZFYVE1 | c.2177A>C p.K726T | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.516); catalogued as COSV100606652; called by muse, mutect2, varscan2
- ZIC4 | c.70+1G>T p.X24_splice | Splice Site (SNP) | VAF 14/85 reads (16%) | catalogued as COSV101267895; called by muse, mutect2, varscan2
- ZMYM2 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101243607, COSV67037069; called by muse, mutect2, varscan2
- ZNF264 | c.34-1G>T p.X12_splice | Splice Site (SNP) | VAF 67/146 reads (46%) | catalogued as COSV99567175; called by muse, mutect2, varscan2
- ZNF462 | c.1880A>G p.D627G | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99471225; called by muse, mutect2, varscan2
- ZNF516 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101487235; called by muse, mutect2, varscan2
- ZNF543 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1441690532, COSV100386711; called by muse, mutect2, varscan2
- ZNF638 | c.4238A>G p.N1413S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs747049488, COSV100038318; called by muse, mutect2, varscan2
- ZNF678 | c.1004A>G p.H335R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.509); catalogued as rs1416285782, COSV100652686; called by muse, mutect2, varscan2
- ZNF680 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100549030; called by muse, mutect2, varscan2
- A4GNT | c.662dup p.N222Qfs*5 | Frame Shift Ins (INS) | VAF 16/95 reads (17%) | called by mutect2, pindel, varscan2
- AHNAK | c.2684del p.P895Qfs*5 | Frame Shift Del (DEL) | VAF 101/352 reads (29%) | called by mutect2, pindel, varscan2
- ALKBH2 | c.165del p.S56Afs*34 | Frame Shift Del (DEL) | VAF 25/116 reads (22%) | called by mutect2, pindel, varscan2
- CAMTA1 | c.2236C>A p.P746T | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.255); called by muse, mutect2
- CD96 | c.1223del p.P408Lfs*10 (on ENST00000283285 / NM_198196.3; = p.P392Lfs*10 on NM_005816.5) | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- FCGBP | c.6532G>T p.V2178L | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- IGHA1 | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- IGHM | c.1140C>A p.S380R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- IGHV1-46 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 58/383 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ING4 | c.88del p.D30Tfs*2 | Frame Shift Del (DEL) | VAF 33/160 reads (21%) | called by mutect2, pindel, varscan2
- KMT2E | c.3362_3393del p.V1121Gfs*7 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- PIK3C2G | c.3281del p.G1094Efs*4 (on ENST00000676171; = p.G1053Efs*4 on NM_004570.5) | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- PLXNA3 | c.2864dup p.S956Lfs*51 | Frame Shift Ins (INS) | VAF 60/114 reads (53%) | called by mutect2, pindel, varscan2
- PPA2 | c.541_542del p.G181Rfs*15 (on ENST00000341695 / NM_176869.3; = p.G152Rfs*15 on NM_006903.4) | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel*
- SPATA31A3 | c.247G>C p.A83P | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by mutect2, varscan2
- TRGV3 | c.80A>T p.K27M | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TUBB8 | c.990del p.M330Ifs*20 | Frame Shift Del (DEL) | VAF 53/173 reads (31%) | called by mutect2, pindel, varscan2
- WASHC2A | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCC8 | c.627C>T p.D209= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs80356640, CM072824; called by muse, mutect2, varscan2
- ACSL6 | c.1836C>A p.A612= (on ENST00000379240; = p.A637= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99733126; called by muse, mutect2, varscan2
- ADGRB3 | c.2706A>G p.L902= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV99484328; called by muse, mutect2, varscan2
- AIRE | c.624G>T p.G208= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV99381032, COSV99381053; called by muse, mutect2, varscan2
- ALDH16A1 | c.1959T>A p.P653= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as rs766118118, COSV99512728; called by muse, mutect2
- AOC2 | c.1023G>T p.L341= | Silent (SNP) | VAF 97/153 reads (63%) | catalogued as COSV99513563; called by muse, mutect2, varscan2
- ARHGEF6 | c.930A>G p.P310= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as COSV99166406; called by muse, mutect2
- ARSB | c.474C>A p.T158= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV99364534; called by muse, mutect2, varscan2
- ATRNL1 | c.2502A>G p.L834= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs782358857, COSV100369973; called by muse, mutect2, varscan2
- BBS12 | c.1092A>T p.T364= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as CD070443, COSV100044879; called by muse, mutect2, varscan2
- BORCS7 | c.228A>T p.I76= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100185635; called by muse, mutect2, varscan2
- C1orf158 | c.174A>G p.P58= | Silent (SNP) | VAF 50/85 reads (59%) | catalogued as COSV99847250; called by muse, mutect2, varscan2
- CARD11 | c.2961G>T p.T987= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as rs368214396, COSV101210630; called by muse, mutect2, varscan2
- CD1E | c.738G>T p.R246= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV100936949; called by muse, mutect2, varscan2
- CHPF | c.2196G>T p.R732= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV99704808; called by muse, mutect2, varscan2
- COL4A1 | c.402G>T p.P134= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as rs761538161, COSV101011037; called by muse, mutect2, varscan2
- CPN2 | c.129C>A p.V43= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as COSV100102985; called by muse, mutect2, varscan2
- CPQ | c.1227C>T p.I409= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as COSV99611249; called by muse, mutect2
- CRB1 | c.1962C>A p.T654= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV100957759, COSV66332528; called by muse, mutect2, varscan2
- CSF2RB | c.2226C>A p.P742= | Silent (SNP) | VAF 117/199 reads (59%) | catalogued as COSV99453529; called by muse, mutect2, varscan2
- CSPG4 | c.5121C>G p.L1707= | Silent (SNP) | VAF 63/142 reads (44%) | catalogued as rs1316915172, COSV100413624, COSV57891416; called by muse, mutect2, varscan2
- CTCFL | c.207G>T p.L69= | Silent (SNP) | VAF 70/123 reads (57%) | catalogued as COSV99712383; called by muse, mutect2, varscan2
- CUX2 | c.1137C>T p.S379= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as COSV99919166; called by muse, mutect2, varscan2
- CYP2A13 | c.1362C>A p.T454= | Silent (SNP) | VAF 71/134 reads (53%) | catalogued as COSV100386697; called by muse, mutect2, varscan2
- CYP2C18 | c.933G>C p.L311= | Silent (SNP) | VAF 49/70 reads (70%) | catalogued as COSV99608303, COSV99608389; called by muse, mutect2, varscan2
- DNAH5 | c.1833A>G p.K611= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99447315; called by muse, mutect2, varscan2
- DSCAM | c.231C>A p.P77= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV101259614; called by muse, mutect2, varscan2
- EHD2 | c.1191G>T p.L397= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV99621790; called by muse, mutect2, varscan2
- ERICH3 | c.4098C>A p.A1366= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs762638364, COSV100443861; called by muse, mutect2, varscan2
- ERP44 | c.450A>G p.L150= | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as rs1157670929, COSV99316292; called by muse, mutect2, varscan2
- FAM47C | c.888G>T p.R296= | Silent (SNP) | VAF 37/60 reads (62%) | catalogued as COSV100792409; called by muse, mutect2, varscan2
- FBN3 | c.7608C>T p.H2536= | Silent (SNP) | VAF 51/112 reads (46%) | catalogued as COSV99560405; called by muse, mutect2, varscan2
- FETUB | c.837C>A p.P279= | Silent (SNP) | VAF 48/233 reads (21%) | catalogued as COSV99408928; called by muse, mutect2, varscan2
- FGF3 | c.495G>A p.R165= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs782492109, COSV100490137; called by muse, mutect2, varscan2
- FMN2 | c.3003C>A p.P1001= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV100144170, COSV60433718; called by muse, varscan2
- FRG2B | c.42C>T p.S14= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as rs774052843, COSV71042421; called by muse, mutect2, varscan2
- GABRA5 | c.417G>A p.K139= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100164934; called by muse, mutect2, varscan2
- GALNT11 | c.1287C>T p.I429= | Silent (SNP) | VAF 59/145 reads (41%) | catalogued as rs1291488861, COSV100231707; called by muse, mutect2, varscan2
- GIMAP1 | c.828G>T p.L276= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100212041; called by muse, mutect2
- GPLD1 | c.858A>G p.A286= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as COSV57761614, COSV57761964; called by muse, mutect2, varscan2
- GPR149 | c.2154T>C p.N718= | Silent (SNP) | VAF 42/172 reads (24%) | catalogued as rs781668501, COSV101078260; called by muse, mutect2, varscan2
- GPR158 | c.2985C>T p.T995= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV100893036, COSV100893078; called by muse, mutect2, varscan2
- GPRC6A | c.318C>A p.V106= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100114200; called by muse, mutect2, varscan2
- HOOK2 | c.1857G>T p.R619= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs1304917990, COSV99317440; called by muse, mutect2, varscan2
- HOXC11 | c.906T>G p.P302= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV99678367; called by muse, varscan2
- IGF1R | c.372T>C p.N124= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99150694; called by muse, mutect2, varscan2
- LAMC2 | c.2511G>T p.A837= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV99917265; called by muse, mutect2, varscan2
- LIN28B | c.151C>A p.R51= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV100558658, COSV104421499; called by muse, mutect2, varscan2
- LUZP2 | c.960T>G p.S320= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV100419432; called by muse, mutect2, varscan2
- MMP12 | c.879C>A p.T293= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs571598878, COSV100404907, COSV100404950; called by muse, mutect2
- MRC1 | c.2946G>C p.G982= | Silent (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2, varscan2
- MTARC2 | c.342C>T p.I114= | Silent (SNP) | VAF 45/153 reads (29%) | catalogued as COSV63766393; called by muse, mutect2, varscan2
- MUC15 | c.37T>C p.L13= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV99846302; called by muse, mutect2, varscan2
- MUC16 | c.41019C>A p.S13673= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV101109743, COSV66692169; called by muse, mutect2, varscan2
- MYH9 | c.4221C>G p.A1407= | Silent (SNP) | VAF 22/149 reads (15%) | catalogued as COSV99338366; called by muse, mutect2, varscan2
- NCAPH | c.1110G>A p.G370= | Silent (SNP) | VAF 72/137 reads (53%) | catalogued as COSV99545682; called by muse, mutect2, varscan2
- NEXMIF | c.3963C>T p.S1321= | Silent (SNP) | VAF 29/50 reads (58%) | catalogued as COSV99280249; called by muse, mutect2, varscan2
- NUP62CL | c.108C>A p.T36= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as COSV100990975; called by muse, mutect2, varscan2
- OR14A16 | c.30T>C p.F10= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100713734; called by muse, mutect2, varscan2
- OR5M11 | c.477C>A p.A159= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV101602028; called by muse, mutect2, varscan2
- ORM1 | c.390T>G p.L130= | Silent (SNP) | VAF 20/264 reads (8%) | catalogued as COSV99407510; called by muse, mutect2
- P2RY10 | c.291C>T p.H97= | Silent (SNP) | VAF 44/79 reads (56%) | catalogued as COSV99409024, COSV99409383; called by muse, mutect2, varscan2
- PEG3 | c.3576C>T p.S1192= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV55629109, COSV99688099; called by muse, mutect2, varscan2
- PKNOX2 | c.390G>T p.L130= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100020509; called by muse, mutect2, varscan2
- PLEKHA6 | c.2007G>T p.R669= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV55336745; called by muse, mutect2, varscan2
- POLRMT | c.1245G>T p.V415= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as COSV101646084; called by muse, mutect2, varscan2
- PSMB11 | c.891T>A p.T297= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99943652; called by muse, mutect2, varscan2
- PTCHD3 | c.727C>A p.R243= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV101438883, COSV71256983; called by muse, mutect2, varscan2
- PTPRR | c.162G>T p.L54= | Silent (SNP) | VAF 49/169 reads (29%) | catalogued as rs138385862; called by muse, mutect2, varscan2
- RB1CC1 | c.1392A>G p.Q464= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs1255500010, COSV99209866; called by muse, mutect2, varscan2
- RECK | c.2754G>C p.P918= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as COSV100937453; called by muse, mutect2, varscan2
- REG1A | c.126C>A p.A42= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as COSV99286711; called by muse, mutect2
- RTTN | c.5316G>T p.A1772= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV55345324, COSV99731672; called by muse, mutect2, varscan2
- SAMSN1 | c.648C>T p.F216= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs770868418, COSV53474409, COSV99581080; called by muse, mutect2, varscan2
- SDK1 | c.2058G>T p.V686= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as COSV101269046; called by muse, mutect2, varscan2
- SFMBT2 | c.1899A>T p.L633= | Silent (SNP) | VAF 49/104 reads (47%) | catalogued as COSV100738719; called by muse, mutect2, varscan2
- SHANK1 | c.648C>A p.P216= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs1276209296, COSV53246362; called by muse, mutect2, varscan2
- SIGLEC1 | c.3552T>C p.H1184= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99163635; called by muse, mutect2, varscan2
- SSU72P8 | c.99C>A p.V33= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs1323236471; called by muse, mutect2, varscan2
- STRN3 | c.1860A>T p.P620= (on ENST00000357479 / NM_001083893.2; = p.P536= on NM_014574.4) | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100670457; called by muse, mutect2, varscan2
- SUSD4 | c.1215C>A p.P405= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100663628; called by muse, varscan2
- SVIL | c.5175C>T p.T1725= (on ENST00000355867 / NM_021738.3; = p.T1299= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as COSV100881139; called by muse, mutect2, varscan2
- TBC1D10C | c.1194C>T p.P398= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100408170; called by muse, mutect2
- TBC1D8B | c.2241A>G p.R747= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV99344109; called by muse, mutect2, varscan2
- TENT4A | c.1791G>T p.L597= | Silent (SNP) | VAF 64/96 reads (67%) | catalogued as COSV100048763; called by muse, mutect2, varscan2
- THSD7B | c.240C>T p.N80= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- TNN | c.3351T>C p.T1117= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV99511529; called by muse, mutect2, varscan2
- TP53BP2 | c.3267C>T p.C1089= (on ENST00000343537 / NM_001031685.3; = p.C960= on NM_005426.2) | Silent (SNP) | VAF 66/213 reads (31%) | catalogued as COSV100636549; called by muse, mutect2, varscan2
- TRIML1 | c.993G>T p.L331= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV100205840, COSV60193317; called by muse, mutect2, varscan2
- TTN | c.56946C>A p.V18982= (on ENST00000591111; = p.V11558= on NM_003319.4) | Silent (SNP) | VAF 52/98 reads (53%) | catalogued as COSV100602473; called by muse, mutect2, varscan2
- TXK | c.1551G>A p.L517= | Silent (SNP) | VAF 8/113 reads (7%) | catalogued as COSV99972282; called by muse, mutect2
- VGLL2 | c.933T>C p.C311= (on ENST00000326274 / NM_182645.3; = p.C137= on NM_153453.1) | Silent (SNP) | VAF 24/267 reads (9%) | catalogued as rs1270107276, COSV100409881; called by muse, mutect2
- WSCD1 | c.213C>A p.A71= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as COSV100496477; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2136G>T p.A712= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV99648375; called by muse, mutect2, varscan2
- ABCF1 | c.-1G>A | 5'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100400772; called by muse, mutect2
- GBA3 | c.59-8596A>G | Intron (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- GLIPR1L2 | c.670+63T>A | Intron (SNP) | VAF 22/42 reads (52%) | catalogued as COSV100248502; called by muse, mutect2, varscan2
- KCNK12 | c.*8477G>A | 3'UTR (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100009642; called by muse, mutect2, varscan2
- MDFIC | c.-24G>C | 5'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99994999; called by muse, varscan2
- MIR422A | n.26G>T | RNA (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- PHIP | c.*1C>G | 3'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99243715; called by muse, mutect2, varscan2
- SLC22A17 | n.1148G>T | RNA (SNP) | VAF 43/124 reads (35%) | catalogued as COSV99071696; called by muse, mutect2, varscan2
- SNORD114-14 | n.62A>T | RNA (SNP) | VAF 19/60 reads (32%) | catalogued as rs752380017; called by muse, mutect2, varscan2
- SNORD116-4 | n.75G>T | RNA (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
